Somatic mutation profile of tumor specimen TCGA-WC-A87Y-01A (aliquot TCGA-WC-A87Y-01A-11D-A39W-08) from TCGA case TCGA-WC-A87Y, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; Age at diagnosis: 59.9 years (21,865 days).
Specimen TCGA-WC-A87Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 840ad06a-1835-435a-9976-0ef8212a376e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WC-A87Y-10A (Blood Derived Normal), aliquot TCGA-WC-A87Y-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b879f4c-a212-42e6-b6e1-c15aa8a3ba96

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AHCTF1 | c.6637G>A p.D2213N (on ENST00000366508; = p.D2187N on NM_015446.5) | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs1013821654; called by muse, mutect2, varscan2
- CHST4 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768338660, COSV58296873; called by muse, mutect2, varscan2
- MYH4 | c.3472G>A p.G1158S | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.7); catalogued as rs764056557, COSV55113103; called by muse, mutect2, varscan2
- TNS4 | c.604A>G p.I202V | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.6); catalogued as rs372464786; called by muse, mutect2, varscan2
- ABHD2 | c.211A>G p.I71V | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ANXA2 | c.461A>T p.D154V | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- PRR14 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- PRRG4 | c.171G>A p.L57= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs1388798496; called by muse, mutect2, varscan2
- RGS11 | c.837C>T p.D279= (on ENST00000397770 / NM_183337.3; = p.D258= on NM_003834.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs370941756, COSV51451845; called by muse, mutect2, varscan2
- SNTG2 | c.1011C>T p.S337= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs1405891115; called by muse, mutect2, varscan2
- CASTOR3 | n.263_279del | RNA (DEL) | VAF 4/22 reads (18%) | called by mutect2, pindel
